HCMI case HCM-CSHL-0657-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6cb73e78-c352-4fed-b206-5eabc02a5045

Demographics
Sex at birth: male; Race: american indian or alaska native; Year of birth: 1973; Vital status: Dead; Cause of death: Cancer Related.

Diagnoses (2)
1. Neuroendocrine carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8246/3; ICD-10 code: C25.4; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 46.5 years (16,996 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Peripancreatic lymph nodes tested: 0.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Lanreotide Acetate; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 37 days; Days to treatment end: 132 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/6; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 46.5 years (16,996 days).
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 0.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 191 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- CHGA (IHC): Negative.
- Ki67 (IHC): 4.6 percent.
- SYP (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86.2 kg; Height: 172.7 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker; Alcohol days per week: 0.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-CSHL-0657-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
